Surgical pathology report (de-identified scan), TCGA case TCGA-BA-A6DD, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-A6DD-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

FSA: Soft tissue, chin, biopsy

- Skeletal muscle and fat, no invasive carcinoma identified

FSB: Left mandible marrow margin, biopsy

- Bone marrow and fibroadipose soft tissue, no invasive carcinoma identified

FSC: Right mandible marrow margin, biopsy

- Bone and fibrous stroma, no invasive carcinoma identified

D: Skin, mandible, tongue and floor of mouth, composite resection

Tumor histologic type: invasive squamous cell carcinoma

Histologic grade: moderately differentiated, focally keratinizing

Primary site: floor of mouth and oral tongue

Tumor laterality: bilateral

Tumor focality: unifocal

Tumor size: 5.6 cm diameter grossly

Extent of invasion: mandible, subcutis, oral tongue, floor of mouth

Vascular: not identified

Perineural: present (D19)

Bone: present (D11, D20)

Ancillary studies:

P16 by IHC: negative

HR HPV by ISH: negative

Carcinoma in situ: not identified

Soft tissue margins:

- Focally involved at left lateral en face mucosal margin (D4)

ICD-O-3

Carcinoma, squamous cell
keratinizing NOS 8071/3

Site ^{CCF} Floor of mouth NOS C04.9

path

Overlapping lesion of other and
unspecified parts of mouth C06.8

gd 5/21/13

[page 2 of 6]
- Others negative, focally close
- 1 mm to inferior (D21)
- 2 mm to right soft tissue margin over mandible (D10)
- 2 mm to right posterolateral soft tissue margin (D14)
- 4 mm to left posterolateral soft tissue margin (D15)
- Right lateral mucosal en face margin: not involved
- En face skin margins: not involved

Bone margins: Not involved

Lymph nodes:

- Metastatic squamous cell carcinoma (2/2) in this specimen
- Size of largest metastasis: 2.1cm
Extra-nodal extension: not identified

Other significant findings: none

AJCC Pathologic Stage: pT4a pN2c pMx

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

E: Lymph nodes, left neck levels 2 and 3, dissection

- Metastatic squamous cell carcinoma (1/18), 0.1 cm diameter, without extracapsular extension (E6,7)

F: Lymph nodes, right neck levels 2 and 3, dissection

- Metastatic squamous cell carcinoma (1/14), 0.4 cm diameter, without extracapsular extension (F4)

G: Lymph nodes, right neck level 4, dissection

- Metastatic squamous cell carcinoma (1/8), 1.1 cm diameter, without extracapsular extension (G4)

Intraoperative Consult Diagnosis:

A frozen section was requested by Dr. in on at

FSA1: Soft tissue of chin, biopsy

- No tumor identified

FSB1: Left mandible marrow margin, biopsy

- No tumor seen

FSC1: Right mandible marrow margin, biopsy

- No tumor seen

[page 3 of 6]
Drs. on _____ at _____ (A) and Drs. on _____
at _____ (B-C).

Frozen Section Pathologist:, MD

Clinical History:

-year-old male with squamous cell carcinoma of the oral cavity.

Gross Description:

Specimen A is received is one appropriately labeled container, additionally labeled "chin biopsy" and consists of two fragments of pink/tan soft tissue measuring 11 x 10 x 5 mm in aggregate, FSA1,

Specimen B is labeled "left mandible marrow margin" and consists of three fragments of red/tan soft tissue, which were 10 x 5 x 2 mm in aggregate, FSB1,

Specimen C is labeled "right mandible marrow margin" and consists of two fragments of red/tan soft tissue, 8 x 4 x 2 mm in aggregate, FSC1,

Specimen D is labeled "composite resection of skin, mandible, tongue and floor of mouth."

Specimen fixation: formalin

Type of specimen: composite resection consisting of anterior skin, anterior half of mandible, anterior third of tongue, and floor of mouth with attached left and right submandibular glands

Size of specimen: Overall size (10.8 x 8.5 x 6.3 cm); skin (5.6 x 5.3 x 1.0 cm depth), mandible (15.3 x 2.7 x 1.3 cm), tongue (5.2 x 3.5 x 2.6 cm), left submandibular gland (4.1 x 2.7 x 2.3 cm), right submandibular gland (4.3 x 3.2 x 2.6 cm), and posterior/inferior soft tissue (6.3 x 4.1 x 3.2 cm)

Laterality: bilateral consisting of left and right mandible

Orientation of specimen: Skin margin is yellow, soft tissue margin overlying the left mandible is red, the soft tissue overlying the right mandible is orange, inferior soft tissue margin is black, left posterior lateral soft tissue margin is green, and right posterior lateral soft tissue margin is blue.

[page 4 of 6]
Tumor size: 5.6 x 3.5 x 3.5 cm

Tumor description: firm, gray/white, ill-defined/infiltrative with a smooth cut surface and superficially ulcerated

Location of tumor: floor of mouth/sublingual

Extent of tumor: tumor extends the anterior mandible and into the subcutaneous tissue, 0.5 cm from the skin surface; the mass extends into the left mandible by 0.4 cm, and into the right mandible by 0.6 cm, the mass extends into the tongue occupying approximately 30% of the tongue

Presence/absence of bone involvement: Present, extends into the left mandible, into the right mandible, and through the anterior mandible

Distance of tumor to surgical margins: tumor is 0.5 cm to the nearest skin margins which is 12 and 6 o' clock, left mandibular bone margin 2.7 cm, right mandibular bone margin 2.8 cm, the right posterior lateral soft tissue margin 0.1 cm, the left posterior lateral soft tissue margin 0.3 cm, left lateral mucosal margin/soft tissue margin 1.0 cm, right lateral mucosal/soft tissue margin 0.3 cm, and inferior soft tissue margin 0.4 cm

Description of remainder of tissue: The left submandibular gland is tan and lobulated with one partly necrotic/cavitary firm white parasubmandibular lymph node (4.0 x 2.8 x 1.5 cm) that grossly abuts the inferior soft tissue margin. The left submandibular gland is free of mass and is grossly abutted by the positive lymph node. The mass is 2.5 cm from the submandibular gland but extends into a 2.7 x 1.7 x 1.0 cm separate glandular structure consistent with left sublingual gland. The right submandibular gland is tan and lobulated, uninvolved by mass (mass is 2.5 cm from the gland). Within the soft tissue adjacent to the right submandibular gland are two firm smooth gray/white lymph nodes, up to 2.0 x 2.0 x 1.5 cm in greatest dimension. These lymph nodes grossly abut the inferior margin. The mass extends into a 2.5 x 1.5 x 0.8 cm right sublingual gland. Along the gingiva are diffusely discolored brown/gray (approximately 7) chipped/jagged teeth.

Lymph nodes: Please see description of remainder of tissue.

Tissue submitted for special investigations: tumor given to

[page 5 of 6]
Digital photograph taken: photos of the intact specimen were taken

Block summary:

- D1,D2 - left mandibular bone margin, en face, following decal
- D3 - right mandibular bone margin, en face, following decal
- D4 - left lateral mucosal margin, en face
- D5 - right lateral mucosal margin, en face
- D6 - skin margin, en face, from 12 to 3 o' clock
- D7 - skin margin, en face, from 3 to 6 o' clock
- D8 - skin margin, en face, from 6 to 9 o' clock
- D9 - skin margin, en face, from 9 to 12 o' clock
- D10 - perpendicular of mass with right soft tissue margin that overlies the mandible
- D11 - mass extending into right mandibular body, following decal
- D12 - perpendicular of mass with the left soft tissue margin that overlies the mandible
- D13 - mass extending into body of left mandible, following decal
- D14 - perpendicular of mass with the right posterior lateral soft tissue margin
- D15 - perpendicular of mass with left posterior lateral soft tissue margin
- D16 - mass into the left sublingual gland
- D17 - mass into the right sublingual gland
- D18 - perpendicular of mass closest to the inferior soft tissue margin
- D19 - mass extending into the subcutaneous tissue with overlying skin
- D20 - mass extending through the anterior mandible, following decal
- D21 - firm lymph node abutting the inferior margin with adjacent left submandibular gland
- D22 - right submandibular gland
- D23 - representative of two firm lymph nodes abutting the inferior margin next to the right submandibular gland

Specimen E is labeled "left neck levels 2 and 3" and consists of a 3.5 x 2.7 x 1.7 cm aggregate of rubbery pink/tan tissue that is dissected for lymph node candidates of which 14 are identified ranging from 0.4 cm in greatest dimension up to 1.5 x 1.3 x 0.7 cm in greatest dimension.

Block Summary:

- E1 - Five lymph node candidates
- E2 - Three lymph node candidates
- E3 - One lymph node candidate
- E4 - Two lymph node candidates, each bisected, one inked blue

[page 6 of 6]
E5 - One lymph node candidate, serially sectioned
E6-E7 - One lymph node candidate, serially sectioned
E8 - One lymph node candidate, bisected

Specimen F is additionally labeled "right neck Level 2, 3." It consists of a 4.6 x 4.2 x 1.2 cm portion of fibrofatty tissue that is dissected for lymph node candidates of which 11 are identified, ranging from 0.3 cm in greatest dimension up to 2.7 x 1.5 x 0.7 cm in greatest dimension. One of the mid-sized lymph nodes has a 0.3 cm in diameter smooth, well circumscribed white nodule that grossly abuts the capsule.

Block Summary:

F1 - five lymph node candidates
F2 - two lymph node candidates, each bisected, one inked green
F3 - one lymph node candidate, serially sectioned
F4 - one lymph node candidate, serially sectioned, with white nodule
F5 - one lymph node candidate
F6-f7 - one lymph node candidate, serially sectioned

Specimen G is additionally labeled "right neck, Level 4." It consists of a 3.4 x 2.6 x 1.0 cm portion of fibrofatty tissue that is bisected for lymph node candidates of which five are identified ranging from 0.4 cm in greatest dimension up to 2.1 x 1.3 x 1.2 cm in greatest dimension. The largest node has a firm, smooth, white cut surface.

Block summary:

G1 - one lymph node
G2 - one lymph node
G3 - two lymph nodes, each bisected, one inked green
G4 - representative of largest lymph node

Source: NCI Genomic Data Commons file fcfbfc06-84c5-4675-9dc4-ae0d4d92052d (TCGA-BA-A6DD.454AB9AE-BA5A-4A07-9839-2A692455A044.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).